Surgical pathology report (de-identified scan), TCGA case TCGA-93-7348, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Washington University - St. Louis, specimen TCGA-93-7348-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY REPORT
FINAL

DIAGNOSIS:

- A. LYMPH NODE, STATION 10, BIOPSY
- ONE LYMPH NODE NEGATIVE FOR TUMOR (0/1)
- B. LYMPH NODE, STATION 11, BIOPSY
- ONE LYMPH NODE NEGATIVE FOR TUMOR (0/1)
- HYALINIZED GRANULOMA
- C. LYMPH NODE, STATION 12, BIOPSY
- ONE LYMPH NODE NEGATIVE FOR TUMOR (0/1)
- D. LUNG, RIGHT UPPER LOBE, LOBECTOMY
- INVASIVE MODERATELY DIFFERENTIATED ADENOCARCINOMA, 1.5 CM
- NO LYMPHOVASCULAR SPACE INVASION IDENTIFIED
- NO PLEURAL INVASION SEEN (CONFIRMED BY VVG ELASTIN STAIN)
- ONE LYMPH NODE NEGATIVE FOR TUMOR (0/1)
- HYALINIZED GRANULOMA
- SURGICAL MARGINS FREE OF TUMOR
- SEE SYNOPSIS
- E. LYMPH NODE, 10R, BIOPSY
- LYMPH NODE WITH HYALINIZED NECROTIC GRANULOMA WITH CALCIFICATIONS NEGATIVE FOR TUMOR (0/1)
- F. LYMPH NODE, 4R, BIOPSY
- LYMPH NODE WITH HYALINIZED GRANULOMA, NEGATIVE FOR TUMOR (0/1)
- G. LYMPH NODE, STATION 7, BIOPSY
- ONE LYMPH NODE NEGATIVE FOR TUMOR (0/1)

[page 2 of 4]
SURGICAL PATHOLOGY REPORT

Intraoperative Consultation:

Intraoperative non-microscopic consultation was obtained and interpreted as: "Brought to frozen 'right upper lobe' consisting of a 226 gram right upper lobe measuring 13 x 9 x 2 cm with a 10 cm staple line. Sectioning shows a 1.5 cm tan firm mass abutting the pleural surface and 4.5 cm from the staple line, and 3 cm from the bronchial margin. The bronchial margin and portion of tumor frozen as FS1A and B, respectively. Rest for permanents, [REDACTED] ID."

FS1A: Right upper lobe bronchial margin

- "Negative for carcinoma, area of necrosis with bacterial and possible fungal elements," [REDACTED] ID.

FS1B: Right upper lobe, excision

- "Adenocarcinoma," by [REDACTED]

Microscopic Description and Comment:

Sections from the hyalinized granuloma of the lung (slide D1) was stained with GMS, PAS, and AFB and show no evidence of fungal organisms or mycobacteria.

[REDACTED]

[REDACTED]

History:

The patient is a [REDACTED] with a lung mass. Operative procedure: Video-assisted thorascopic right upper lobectomy.

[REDACTED]

Specimen(s) Received:

A: LYMPH NODE, STATION 10
B: LYMPH NODE, STATION 11
C: LYMPH NODE, STATION 12
D: LUNG, RIGHT UPPER LOBE
E: LYMPH NODE, 10 R
F: LYMPH NODE, 4 R
G: LYMPH NODE, STATION 7

Gross Description:

The specimens are received in seven formalin-filled containers, each [REDACTED]. The first container is labeled "station 10 lymph node." It contains two fragments of tan-black tissue measuring 0.8 x 0.8 cm in aggregate. Labeled A1. Jar 0.

[REDACTED]

The second container is labeled "station 11 lymph node." It contains multiple fragments of tan-brown tissue measuring 1.2 x 1.2 cm in aggregate. Labeled B1. Jar 0.

The third container is labeled "station 12 lymph node." It contains multiple fragments of tan-brown tissue measuring 1 x 1 cm in aggregate. Labeled C1. Jar 0.

The fourth container is labeled "right upper lobe and FS1A/B/X." It contains a right upper lobe as previously described with the characteristics and measurements within the intraoperative non-microscopic consultation. Further sectioning shows a 1.5 cm, tan-brown nodule to be indistinct and located abutting the pleural surface and greater than 3 cm away from the surgical resection parenchymal margin and bronchial margin. There is a second round hyalinized hard mass measuring 1 x 1 x 1 cm, also abutting the pleural surface and greater than 3 cm from the surgical resection margins.

[page 3 of 4]
SURGICAL PATHOLOGY REPORT

The surgical staple line is removed and the underlying parenchyma is inked. Labeled D1 to D3 - hyalinized nodule and surrounding pleura and parenchyma, entirely submitted; D4 and D5 - shave of surgical resection margin; D6 - normal-appearing parenchyma. The container also holds two cassettes labeled 'FS1A and B' holding the frozen section remnant, FS1A and B. Labeled D7 and D8. Labeled D9 to D13 - tumor and surrounding pleura and parenchyma, entirely submitted. Jar 2.

The fifth container is labeled "10R lymph node." It contains a single tan, firm lymph node measuring 1 x 1 x 0.5 cm. Bisected to show putative positive metastatic disease. Labeled E1. Jar 0.

The sixth container is labeled "station 4R lymph node." It contains a 1.5 x 1 x 0.3 cm, tan, firm lymph node. Labeled F1. Jar 0.

The seventh container is also labeled "station 7 lymph node." It contains a fragment of tan-brown tissue measuring 0.5 x 0.5 x 0.3 cm. Labeled G1. Jar 0.

SYNOPTIC REPORTING FORM FOR LUNG CARCINOMA

NEOPLASM

A neoplasm is present

HISTOPATHOLOGIC TYPE

The histologic classification of the tumor is adenocarcinoma, acinar (usual) type

HISTOLOGIC GRADE (G)

The grade of the tumor is moderately differentiated (G2)

TUMOR SIZE

The maximum dimension of the tumor is 1.5 cm

LYMPHATIC INVASION

Lymphatic invasion by tumor is not identified (L0)

VENOUS INVASION

Venous invasion by tumor is not identified (V0)

ARTERIAL INVASION

Arterial invasion by tumor is not identified

PLEURAL INVOLVEMENT

Pleural involvement is absent

SAMPLED SPECIMEN MARGINS

The sampled surgical margins are uninvolved by tumor

NON-NEOPLASTIC TISSUE

Hemorrhage

PRIMARY TUMOR (T)

Tumor <= 2 cm in greatest dimension (T1a)

REGIONAL LYMPH NODES (N)

No regional lymph node metastasis histologically; no examination for ITC (pN0)

The total number of lymph nodes examined is 7

The total number of metastatically-involved lymph nodes is 0

DISTANT METASTASIS (M)

Distant metastasis cannot be assessed (MX)

[page 4 of 4]
SURGICAL PATHOLOGY REPORT

STAGE GROUPING

The overall international stage is pT1a/N0/Mx

The pathologic stage assigned here should be regarded as provisional, and may change after integration of clinical data not provided with this specimen.

Source: NCI Genomic Data Commons file 8c003690-9717-42a9-9260-8282b09e7c58 (TCGA-93-7348.2AD907AD-1005-4E89-91B8-D09A173BCD4D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).